Somatic mutation profile of tumor specimen TCGA-12-3653-01A (aliquot TCGA-12-3653-01A-01W-0922-08) from TCGA case TCGA-12-3653, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.3 years (12,529 days).
Specimen TCGA-12-3653-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7b839d6-1da7-4304-ac35-35665292823b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3653-10A (Blood Derived Normal), aliquot TCGA-12-3653-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0e8e380-5777-4f65-89ff-fd91e58a6cdf

The open-access MAF lists 34 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Frame Shift Ins 5, Silent 4, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 56/545 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958562, COSV55958958; called by muse, mutect2, varscan2
- ACAP1 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV50139169; called by muse, mutect2, varscan2
- AHCTF1 | c.109C>T p.R37* (on ENST00000366508; = p.R11* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as rs866640499, COSV100403238; called by muse, mutect2
- ARL4D | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV60721725; called by muse, mutect2, varscan2
- CDH9 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 158/282 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751593635, COSV50256584; called by muse, mutect2, varscan2
- CFAP57 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 216/434 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs142914910; called by muse, mutect2, varscan2
- CFAP74 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs150108692; called by muse, mutect2, varscan2
- COL28A1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768670774, COSV68083736; called by muse, mutect2, varscan2
- F13A1 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as COSV53564199; called by muse, mutect2, varscan2
- GRM3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs571579021, COSV64471709, COSV64473083; called by muse, mutect2
- HEPHL1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 326/553 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1565360317, COSV59892403; called by muse, mutect2, varscan2
- HOXB3 | c.797dup p.Q267Afs*30 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as rs762955717; called by mutect2, pindel, varscan2
- ITSN1 | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV66084913; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 19/164 reads (12%) | catalogued as rs774820321; called by mutect2, varscan2
- KIF20B | c.3598A>G p.N1200D (on ENST00000371728 / NM_001284259.2; = p.N1160D on NM_016195.4) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV53312602; called by muse, mutect2, varscan2
- KRTAP10-3 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 617/942 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs781793784, COSV59973345; called by muse, mutect2, varscan2
- LMX1A | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 38/78 reads (49%) | catalogued as rs1310771479, COSV54225542; called by muse, mutect2, varscan2
- LRP1B | c.10676G>A p.R3559Q | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145915063; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- P4HTM | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV59086373; called by muse, mutect2, varscan2
- PGR | c.2437G>T p.V813F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV54807685; called by muse, mutect2, varscan2
- PIAS3 | c.1804dup p.A602Gfs*42 | Frame Shift Ins (INS) | VAF 16/130 reads (12%) | catalogued as rs782068335; called by mutect2, varscan2
- PKHD1 | c.10000A>G p.K3334E | Missense Mutation (SNP) | VAF 143/307 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV61889104; called by muse, mutect2, varscan2
- SMARCA1 | c.2172A>C p.Q724H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV64413186; called by muse, mutect2, varscan2
- TRPV6 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.263); catalogued as rs745408146, COSV63890716; called by muse, mutect2, varscan2
- TUBB4A | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs552079378, COSV51152259; called by muse, mutect2, varscan2
- ZYX | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.829); catalogued as COSV59557156; called by muse, mutect2, varscan2
- MAP4K5 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- XK | c.756dup p.W253Lfs*13 | Frame Shift Ins (INS) | VAF 52/211 reads (25%) | called by mutect2, pindel, varscan2
- ZNF701 | c.1111_1114del p.K371Ffs*69 (on ENST00000301093; = p.K305Ffs*69 on NM_018260.3) | Frame Shift Del (DEL) | VAF 69/150 reads (46%) | called by mutect2, pindel, varscan2
- NPTX2 | c.1044C>T p.G348= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs756266964, COSV55717138; called by muse, mutect2, varscan2
- NTF3 | c.390G>A p.A130= | Silent (SNP) | VAF 63/365 reads (17%) | catalogued as COSV58417644; called by muse, mutect2, varscan2
- PJVK | c.603C>T p.F201= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs762131024, COSV64307003; called by muse, varscan2
- TNS4 | c.1848G>A p.T616= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as rs779189274, COSV54187189; called by muse, mutect2, varscan2
